Somatic mutation profile of tumor specimen TCGA-91-6847-01A (aliquot TCGA-91-6847-01A-11D-1945-08) from TCGA case TCGA-91-6847, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 62.6 years (22,862 days).
Specimen TCGA-91-6847-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef9b37f3-5d66-4e92-83e1-33189555f805.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-91-6847-11A (Solid Tissue Normal), aliquot TCGA-91-6847-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/184ad1e4-efa0-4528-a18f-4b96e0be51e3

The open-access MAF lists 77 somatic variants for this specimen: 51 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 23, Nonsense Mutation 6, Frame Shift Del 2, Intron 1, 3'UTR 1, Splice Site 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 55/73 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM1 | c.161A>T p.Y54F | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV54633551; called by muse, mutect2, varscan2
- AGBL1 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV69794629; called by muse, mutect2, varscan2
- AKR7A2 | c.752T>C p.F251S | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52515833; called by muse, mutect2, varscan2
- ARHGEF26 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754708272, COSV62843732; called by muse, mutect2, varscan2
- ASH1L | c.6157C>T p.P2053S (on ENST00000368346 / NM_001366177.2; = p.P2048S on NM_018489.3) | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV64206351; called by muse, mutect2, varscan2
- C8orf34 | c.773T>G p.V258G | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV61373758; called by muse, mutect2, varscan2
- CA2 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 29/154 reads (19%) | catalogued as COSV53406052, COSV53408449, COSV99570386; called by muse, mutect2, varscan2
- CCDC144A | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV60697059; called by muse, mutect2, varscan2
- CCNE2 | c.903G>C p.L301F | Missense Mutation (SNP) | VAF 46/272 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.15); catalogued as rs891985872, COSV57375189; called by muse, mutect2, varscan2
- CEP152 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV57857634; called by muse, mutect2
- CHIA | c.406G>T p.D136Y (on ENST00000343320; = p.D28Y on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58474235; called by muse, mutect2, varscan2
- CLEC3A | c.170T>C p.I57T (on ENST00000651443; = p.I48T on NM_005752.6) | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs773396988, COSV55220182; called by muse, mutect2, varscan2
- CPT1C | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as rs753309074, COSV54918161; called by muse, mutect2, varscan2
- DNAI2 | c.638T>A p.L213Q | Missense Mutation (SNP) | VAF 97/621 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56757423; called by muse, mutect2, varscan2
- ENTHD1 | c.758C>A p.A253E | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.08); catalogued as rs746091066, COSV57318085; called by muse, mutect2, varscan2
- EPHA10 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1320390986, COSV60402486; called by muse, mutect2, varscan2
- FAM71A | c.302A>C p.H101P | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.151); catalogued as COSV54234927; called by muse, mutect2, varscan2
- GRHL3 | c.1118A>G p.N373S (on ENST00000350501 / NM_198174.3; = p.N378S on NM_021180.3) | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV52565027; called by muse, mutect2
- HTR3D | c.931G>A p.A311T (on ENST00000382489 / NM_001163646.2; = p.A136T on NM_182537.3) | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.435); catalogued as rs113942045, COSV61913547; called by muse, mutect2, varscan2
- INTU | c.481G>T p.V161L | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV56538606; called by muse, mutect2, varscan2
- KALRN | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as rs750456225, COSV53756036; called by muse, mutect2, varscan2
- KANK4 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV62985795; called by muse, mutect2, varscan2
- KCNH8 | c.1122G>C p.W374C | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60458573, COSV60464039; called by muse, mutect2, varscan2
- LRRC27 | c.1416+2T>G p.X472_splice | Splice Site (SNP) | VAF 6/60 reads (10%) | catalogued as COSV63996410; called by muse, mutect2
- MAP4K3 | c.1570G>C p.E524Q | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.066); catalogued as COSV55711051; called by mutect2, varscan2
- MYH4 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs764461718, COSV55114145; called by muse, mutect2, varscan2
- NECTIN3 | c.1045G>C p.D349H | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV60550296; called by muse, mutect2, varscan2
- NEK5 | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62879241, COSV62880836; called by muse, mutect2
- NPC1L1 | c.3886G>A p.V1296I | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs201187589, COSV56922923; called by muse, mutect2, varscan2
- OPLAH | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.28); catalogued as rs200399200; called by muse, mutect2
- OR52E6 | c.398G>A p.W133* | Nonsense Mutation (SNP) | VAF 59/289 reads (20%) | catalogued as COSV61431571; called by muse, mutect2, varscan2
- OR8H3 | c.705G>C p.Q235H | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as rs1281451566, COSV100538744, COSV57907222, COSV57907840; called by muse, mutect2, varscan2
- PHF21B | c.1172G>A p.W391* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV57556716; called by muse, varscan2
- RB1 | c.289del p.E97Nfs*14 | Frame Shift Del (DEL) | VAF 143/214 reads (67%) | catalogued as CD931046; called by mutect2, pindel, varscan2
- RSPH1 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 12/124 reads (10%) | catalogued as COSV52318609; called by muse, mutect2
- RYR2 | c.12323A>G p.H4108R | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63670500; called by muse, mutect2, varscan2
- SCN2B | c.5A>T p.H2L | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.035); catalogued as COSV54050239; called by muse, mutect2, varscan2
- SCRT2 | c.698C>A p.S233* | Nonsense Mutation (SNP) | VAF 22/32 reads (69%) | catalogued as COSV55729015; called by muse, mutect2, varscan2
- SPSB3 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51905027; called by muse, mutect2, varscan2
- STEAP3 | c.256G>C p.V86L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV61528114; called by muse, mutect2, varscan2
- STK38 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 24/318 reads (8%) | catalogued as COSV57707873; called by muse, mutect2
- SUPT6H | c.3183G>C p.E1061D | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV58925400; called by muse, mutect2, varscan2
- TBC1D31 | c.2864G>A p.R955H | Missense Mutation (SNP) | VAF 57/82 reads (70%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766203135, COSV54864513; called by muse, mutect2, varscan2
- TFF1 | c.106dup p.R36Pfs*2 | Frame Shift Ins (INS) | VAF 6/62 reads (10%) | catalogued as rs766192241; called by pindel, varscan2
- ULK4 | c.2233T>G p.S745A | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV57202050; called by muse, mutect2
- VWA5A | c.227A>C p.E76A | Missense Mutation (SNP) | VAF 75/115 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV63707369; called by muse, mutect2, varscan2
- WDPCP | c.280A>G p.N94D | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55415073; called by muse, mutect2
- ZNF311 | c.1341G>T p.Q447H | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV65852948; called by muse, mutect2
- LPP | c.115_119del p.Q39Afs*14 | Frame Shift Del (DEL) | VAF 27/163 reads (17%) | called by mutect2, pindel, varscan2
- ZNF280A | c.751G>C p.A251P | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2
- AHNAK | c.13362C>T p.I4454= | Silent (SNP) | VAF 17/276 reads (6%) | catalogued as COSV57206488; called by muse, mutect2
- AIMP2 | c.891C>T p.A297= | Silent (SNP) | VAF 36/129 reads (28%) | catalogued as COSV52237084; called by muse, mutect2, varscan2
- CLEC1A | c.234C>T p.L78= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV59531217; called by muse, mutect2, varscan2
- CYP26B1 | c.1137C>T p.F379= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs188235033, COSV50011014; called by muse, mutect2, varscan2
- DIS3 | c.63C>G p.R21= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV58321216; called by muse, mutect2, varscan2
- ERICH5 | c.366G>A p.E122= | Silent (SNP) | VAF 12/172 reads (7%) | catalogued as COSV59315319; called by muse, mutect2
- FAM3C | c.660A>T p.G220= | Silent (SNP) | VAF 89/188 reads (47%) | catalogued as COSV63435078; called by muse, mutect2, varscan2
- FDCSP | c.249C>T p.S83= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs200937610, COSV58764470; called by muse, mutect2, varscan2
- GABRA2 | c.204C>G p.V68= | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as COSV100734033, COSV62912937; called by muse, mutect2, varscan2
- LAMB3 | c.417C>T p.F139= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs201554705, COSV61915721; ClinVar: likely benign; called by muse, mutect2, varscan2
- MED13L | c.1905T>C p.S635= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV56117117; called by muse, mutect2, varscan2
- NODAL | c.816C>T p.N272= | Silent (SNP) | VAF 27/40 reads (68%) | catalogued as rs774058854, COSV54660756; called by muse, mutect2, varscan2
- OR4D6 | c.783C>T p.P261= | Silent (SNP) | VAF 50/155 reads (32%) | catalogued as rs754384367, COSV55659247; called by muse, mutect2, varscan2
- OR4K5 | c.273C>G p.T91= | Silent (SNP) | VAF 32/678 reads (5%) | catalogued as COSV60002643; called by muse, mutect2
- PLAU | c.522G>A p.R174= | Silent (SNP) | VAF 44/338 reads (13%) | catalogued as COSV65640996, COSV65641131; called by muse, mutect2, varscan2
- PRKAR2B | c.1035G>A p.S345= | Silent (SNP) | VAF 41/88 reads (47%) | catalogued as rs1392869712, COSV55923169, COSV99708294; called by muse, mutect2, varscan2
- SETBP1 | c.2310G>A p.A770= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs373845529; ClinVar: likely benign; called by muse, mutect2, varscan2
- SHPRH | c.2322A>G p.V774= | Silent (SNP) | VAF 47/93 reads (51%) | catalogued as rs1220756641, COSV51606024; called by muse, mutect2, varscan2
- TENM1 | c.3972G>T p.G1324= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV64427224; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1671T>C p.D557= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV64100062; called by muse, mutect2, varscan2
- ZFP36 | c.822G>C p.L274= (on ENST00000594442; = p.L268= on NM_003407.5) | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as rs777948625, COSV50527539, COSV50528449; called by mutect2, varscan2
- ZNF280A | c.750G>T p.L250= | Silent (SNP) | VAF 12/265 reads (5%) | catalogued as COSV57481846; called by muse, mutect2
- ZNF835 | c.417G>A p.A139= | Silent (SNP) | VAF 38/118 reads (32%) | catalogued as rs962514146, COSV73379261; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504855 A>C | 5'Flank (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- CSMD3 | c.178+59893G>C | Intron (SNP) | VAF 29/186 reads (16%) | called by muse, mutect2, varscan2
- FGF8 | c.*2T>C | 3'UTR (SNP) | VAF 14/25 reads (56%) | catalogued as COSV100199490; called by muse, mutect2, varscan2
